Gene-level copy-number profile of tumor specimen TCGA-35-4123-01A from TCGA case TCGA-35-4123, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 38.5 years (14,064 days).
Specimen TCGA-35-4123-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.c4ad46bb-26c4-4267-a0c2-cb0983719465.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-35-4123-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40d3d120-0cc2-4023-8b4b-29c8cca84477

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 14,322; copy number 2: 30,142; copy number 3: 9,626; copy number 4: 5,274; copy number 5: 455.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-35-4123-01A-01D-1877-01): tumor purity 0.4, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 455 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:176,207,648–176,447,919, 1 gene, copy number 5 (within-gene range 4–5): AL591043.2.
- chr1:176,272,483–176,845,601, 5 genes, copy number 5 (within-gene range 2–5): AL359265.1, AL591043.1, MORF4L1P7, PAPPA2, PTP4A1P7.
- chr8:54,247,633–84,921,844, 449 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,919. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
